Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMT, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMT-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

DIAGNOSIS:

RADICAL CYSTECTOMY WITH URINARY DIVERSION AND STUDER POUCH G-TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (C):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- POSITIVE FOR METASTATIC CARCINOMA

FINAL DIAGNOSIS:

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF TWO LYMPH NODES EXAMINED (1/2)

APICAL URETHRAL MARGIN (D):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETHRAL MARGIN WITH FOCAL CHRONIC INFLAMMATION

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

BLADDER, UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES (E):

BLADDER:

- INVASIVE URETHRAL CARCINOMA, HIGH GRADE 4/4, INFILTRATING THROUGH THE MUSCULARIS PROPRIA INTO THE PERITONEUM SURFACE WITH SQUAMOUS DIFFERENTIATION, EXTENSIVE ULCERATION AND NECROSIS IN THE POSTERIOR OF THE BLADDER
- FOCUS OF UROTHELIAL CARCINOMA IN SITU (FLAT LESION) IDENTIFIED
- LYMPHOVASCULAR INVASION IDENTIFIED
- NON-NEOPLASTIC BLADDER MUCOSA SHOWING CHRONIC CYSTITIS

UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES:

- CERVIX, BENIGN CERVICAL MUCOSA WITH NO EVIDENCE OF DYSPLASIA OR CARCINOMA
- ENDOMETRIUM, BENIGN ENDOMETRIUM SHOWING CYSTIC ATROPHY
- MYOMETRIUM AND SEROSA, NO SIGNIFICANT HISTOPATHOLOGIC FEATURES
- RIGHT OVARY, BENIGN OVARIAN CYST
- LEFT OVARY, MULTIPLE BENIGN INCLUSION CYST
- RIGHT FALLOPIAN TUBE, UNREMARKABLE
- LEFT FALLOPIAN TUBE, BENIGN PARATUBAL CYST

PERIVESICAL LYMPH NODES:

- METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (2/2) WITH EXTRANODAL INVOLVEMENT

LEFT PARA AORTIC LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT PARACAVAL LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

ICD O-3
Carcinoma, urothelial NOS
8126/3
Site: Bladder NOS
C67.9
W 3/26/14

Pv TSS, squamous = 10%

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

LEFT COMMON ILIAC LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT COMMON ILIAC LYMPH NODES (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT LYMPH NODE OF CLOQUET (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (L):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OUT OF TEN LYMPH NODES EXAMINED (1/10) WITH EXTRANODAL INVOLVEMENT

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN 12 LYMPH NODES (0/12)

LEFT LYMPH NODE OF CLOQUET (N):

- MATURE ADIPOSE AND FIBROUS CONNECTIVE TISSUE
- NO LYMPHOID TISSUE OR CARCINOMA IDENTIFIED (0/0)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT PRESACRAL LYMPH NODES (P):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OUT OF SIX LYMPH NODES EXAMINED (1/6)

PRESACRAL LYMPH NODES (Q):

- NO METASTATIC CARCINOMA IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT PRESACRAL LYMPH NODES (R):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

RIGHT PROXIMAL URETER (T):

- BENIGN URETER
- NO DYSPLASIA OR CARCINOMA IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN FIVE OUT OF 74 LYMPH NODES EXAMINED (5/74)

PATHOLOGIC TNM STAGE: pT3bN2MX (AJCC-5TH EDITION)

Electronically signed by
Verified:

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

Location:

COMMENT:

notified of the result on

SPECIMEN SOURCE:

A: "Rt distal ureter"
B: "Lt distal ureter"
C: "Rt obturator/hypogastric FS"
D: "Apical urethral margin F/S"
E: "Bladder, uterus, fallopian tubes"
F: "Lt para aortic lymph nodes"
G: "Rt para caval lymph nodes"
H: "Lt common iliac lymph nodes"
I: "Rt common iliac lymph nodes"
J: "Rt external iliac lymph nodes"
K: "Rt lymph node of cloquet"
L: "Right obturator/hypogastric lymph nodes perm."
M: "Lt ext. iliac lymph node"
N: "Lt lymph node of cloquet"
O: "Lt obturator/hypogastric "
P: "Rt presciatic lymph nodes"
Q: "Pre sacral lymph nodes"
R: "Lt pre sciatic lymph nodes"
S: "Lt proximal ureter"
T: "Rt proximal ureter"

CLINICAL INFORMATION:

Pre-op Dx: High grade muscle invasive bladder cancer

Post-op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Rt distal ureter". It consists of a segment of ureter measuring 0.3 cm in length x 0.3 cm in diameter. The specimen is totally submitted for frozen section in AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt distal ureter". It consists of a segment of ureter measuring 0.3 cm in length x 0.2 cm in diameter. The specimen is totally submitted for frozen section in BFS.

C: The specimen is received fresh from the O.R. and labeled "Rt obturator/hypogastric FS". It consists of yellow-tan lobulated adipose tissue measuring 2.2 x 0.6 x 0.3 cm. Two lymph nodes are identified within the adipose tissue, the smaller lymph node measures 0.7 x 0.6 x 0.3 cm, and the larger lymph node measures 1 x 0.6 x 0.3 cm which is bisected. The specimen is totally submitted for frozen section in CFS.

D: The specimen is received fresh from the O.R. and labeled "Apical urethral margin F/S". It consists of two fragment of pink-tan soft tissue strips ranging in size from 1 to 2.1 cm in length, the larger fragment measures 0.2 cm in diameter, and the smaller measures 0.1 cm in diameter. The specimen is totally submitted for frozen section in DFS.

E: The specimen is received fresh from the O.R. and labeled "Bladder, uterus, fallopian tubes". It consists of a composite resection of a bladder, uterus, bilateral tubes and ovary measuring overall 20.8 x 13.5 x 4 cm. A flap of peritoneal fat present measuring 20.8 x 9 x 3 cm. On the tope of the tumor is a 4.0 x 1.3 cm of serosal surface that is puckered and irregular. The bladder itself measures 7.5 x 9 x 2 cm. The resection margins are inked black. The bladder is opened along its anterior wall. The uninvolved bladder wall measures 1.2 cm in

[page 4 of 7]
Collected
Ordered by

Location

thickness. Opening the bladder wall reveals an ulcerated well-circumscribed tumor involving most of the posterior wall measuring 10.8 x 4.8 x 3.5 cm. The tumor grossly involves the full thickness of the bladder, especially at the area of the serosal puckering. The right and left ureterovesical junctions are identified and are patent. The right ureter measures 6 cm in length x 0.5 cm in circumference and the junction is 1.1 cm away from the tumor mass. The left ureter measures 3 cm in length x 0.5 cm in circumference and the junction is 1.8 cm away from the major tumor mass. Both ureters are grossly unremarkable. Overall the uterus measures 15 x 6 x 2.5 cm. The serosal surface is unremarkable. The cervix measures 3.5 x 2.5 cm and is surrounding a 0.5 cm slit-like cervical os. The pear-shaped uterus measures 5 x 4 x 2.1 cm. The uterine cavity measures 2.5 x 0.7 cm with a 2 cm in length of unremarkable cervical canal. The endomyometrial wall thickness averages 1.1 cm. The endometrium measures 0.1 cm and the myometrium measures 1 cm. The right ovary is cystic and measures 4.8 x 4 x 2.5 cm. The cyst is smooth and is filled with clear fluid. The congruent unremarkable right fallopian tube measures 7 cm in length x 0.3 cm in diameter. The left unremarkable ovary measures 2.2 x 1.5 x 0.7 cm with a congruent unremarkable left fallopian tube measures 5.5 cm in length x 0.3 cm in diameter. Representative sections are submitted in 24 cassettes.

F: The specimen is received in formalin and labeled "Lt para aortic lymph nodes". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 3 x 2 x 1 cm. Three lymph nodes are identified within the adipose tissue ranging 0.7 to 1.3 cm in greatest dimension. The larger lymph node is bisected and totally embedded in two cassettes.

G: The specimen is received in formalin and labeled "Rt para caval lymph nodes". It consists of two fragments of yellow-tan lobulated adipose tissue weighing 4 grams and measuring 2.3 to 3.1 cm in greatest dimension. A single lymph node is identified within the adipose tissue measuring 2 x 1 x 0.6 cm. The lymph node is bisected and totally embedded in two cassettes.

H: The specimen is received in formalin and labeled "Lt common iliac lymph nodes". It consists of yellow-tan lobulated adipose tissue weighing 7 grams and measuring in aggregate 5 x 2 x 1 cm. Five lymph nodes are identified within the adipose tissue ranging size from 0.5 to 2.1 cm. The specimen is totally embedded in five cassettes.

I: The specimen is received in formalin and labeled "Rt common iliac lymph nodes". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 3 x 2 x 1 cm. Three lymph nodes are identified within the adipose tissue ranging 0.7 to 1.3 cm in greatest dimension. The larger lymph node is bisected and totally embedded in five cassettes.

J: The specimen is received in formalin and labeled "Rt external iliac lymph nodes". It consists of multiple fragments of yellow-tan lobulated adipose tissue weighing 6 grams and measuring in aggregate 6 x 3 x 2 cm. Two lymph nodes are identified within the adipose tissue measuring 1.9 to 2.3 cm. The is totally embedded in four cassettes.

K: The specimen is received in formalin and labeled "Rt lymph node of cloquet". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 2 x 1 x 0.7 cm. A single lymph nodes is identified within the adipose tissue measuring ranging 1.2 x 0.9 x 0.6 cm. The lymph node is bisected and totally embedded in one cassette.

L: The specimen is received in formalin and labeled "Right obturator/hypogastric lymph nodes perm.". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 7 x 2 x 0.7 cm. The specimen is is bisected and totally embedded in three cassettes.

[page 5 of 7]
Collected

Ordered by

Location

M: The specimen is received in formalin and labeled "Lt ext. iliac lymph node". It consists of multiple fragments of yellow-tan lobulated adipose tissue weighing 8 grams and measuring in aggregate 5 x 3 x 1 cm. The larger lymph node is bisected and totally embedded in five cassettes.

N: The specimen is received in formalin and labeled "Lt lymph node of cloquet". It consists of multiple yellow-tan lobulated adipose tissue weighing 2 grams and measuring in aggregate 2 x 1 x 0.7 cm. No lymph nodes are identified within this adipose tissue. The specimen is totally embedded in one cassette.

O: The specimen is received in formalin and labeled "Lt obturator/hypogastric". It consists of yellow-tan lobulated adipose tissue weighing 5 grams and measuring 7 x 2 x 0.7 cm. A single lymph node is identified within the adipose tissue measuring 3.4 cm in greatest length. The specimen is bisected and totally embedded in two cassettes.

P: The specimen is received in formalin and labeled "Rt presciatic lymph nodes". It consists of yellow-tan lobulated adipose tissue measuring in aggregate 4 x 2.5 x 1.5 cm. Three lymph nodes are identified within the adipose tissue ranging 0.5 to 1 cm in greatest dimension. The specimen is totally embedded in two cassettes.

Q: The specimen is received in formalin and labeled "Pre sacral lymph nodes". It consists of hemorrhage lobulated adipose tissue measuring in aggregate 4 x 3 x 1 cm. Three lymph nodes are identified within the adipose tissue ranging 0.2 to 1.1 cm. The specimen is totally embedded in four cassettes.

R: The specimen is received in formalin and labeled "Lt pre sciatic lymph nodes". It consists of yellow-tan lobulated adipose tissue measuring 1 x 0.6 x 0.5 cm. A single lymph node is identified within the adipose tissue ranging 0.9 x 0.5 x 0.4 cm. The larger lymph node is bisected and totally embedded in one cassette.

S: The specimen is received in formalin and labeled "Lt proximal ureter". It consists of a segment of ureter measuring 2 cm in length x 0.6 cm in diameter. Two staples are present which are closer to one end. The opposite end of clips are inked black. The specimen is serial sectioned and totally embedded in one cassette.

T: The specimen is received in formalin and labeled "Rt proximal ureter". It consists of a segment of ureter measuring 0.8 cm in length x 0.4 cm in diameter. The specimen is bisected and totally embedded in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, right obturator/hypogastric
DFS: frozen section, apical urethral margin
E1-3: tumor showing full thickness
E4-10: representative sections of tumor with adjacent mucosa
E11: left ureterovesical junction
E12: right ureterovesical junction
E13: representative section of bladder mucosa
E14: right ovary, tube and fimbria
E15: left ovary, tube and fimbria
E16: posterior cervix
E17: anterior cervix
E18: posterior full thickness endomyometrium
E19: anterior endomyometrial wall
E20-21: possible lymph nodes from the left perivesical fat
E22-24: possible lymph nodes from the right perivesical fat

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

F1: one large lymph node
F2: smaller lymph node as well as remaining tissue
G1: one larger lymph node, bisected
G2: remaining adipose tissue
H1-3: lymph nodes (one node each cassette)
H4: lymph nodes
H5: remaining adipose tissue
I1: lymph node
I2-3: remaining adipose tissue
J1-2: possible lymph nodes
J3-4: remaining adipose tissue
K: right lymph node of cloquet, bisected
L1-2: possible lymph nodes
L3: remaining adipose tissue
M1-3: possible lymph nodes
M4-5: remaining tissue
N: left lymph node of cloquet
O1: lymph node, bisected
O2-3: remaining adipose tissue
P1: lymph node
P2: remaining adipose tissue
Q1: possible lymph node
Q2-4: remaining adipose tissue
R: left pre sciatic lymph nodes
S: left proximal ureter
T: right proximal ureter

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter
- negative

BFS: Left distal ureter
- negative

CFS: Right obturator/hypogastric
- positive for metastatic carcinoma

DFS: Apical urethral margin
- negative

MICROSCOPIC EXAMINATION:

A-D: See final microscopic-diagnosis.

E: Sections show invasive urothelial carcinoma infiltrating through the muscularis propria into the peritoneum surface with squamous differentiation, extensive ulceration and necrosis. Neoplastic cells are characterized by pleomorphic nuclei with high N/C ratio, vesicular chromatin and prominent nucleoli with moderate to abundant clear cytoplasm. Mitotic figures are easily identified more than 20 per 10 high power fields. Squamous differentiation with intercellular bridge is present. Surrounding the tumor is desmoplastic change with occasional lymphoplasmacytic infiltrate. A small focus of urothelial carcinoma in situ (flat lesion) is noted. Adjacent urothelial mucosa shows chronic cystitis. Bilateral ureter and vesical junction are uninvolved by tumor. Sections of the uterus show benign cervical mucosa, atrophic endometrium with cystic atrophy and

[page 7 of 7]
Collected

Ordered by

Location

unremarkable myoepithelium and serosal surface. The right ovary displays a benign ovarian cyst. The left ovary shows multiple benign inclusion cyst. The right fallopian tube is unremarkable and the left fallopian tube shows multiple small paratubal cysts.

F-T: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 2e2a94e4-79b7-41f8-ac86-323a055aa9f8 (TCGA-XF-AAMT.DDAC8877-7594-4939-B98F-0BAB7D3CDBB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).